Somatic mutation profile of tumor specimen TARGET-40-NAAGKC-01A (aliquot TARGET-40-NAAGKC-01A-01D) from TARGET case TARGET-40-NAAGKC, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 10.2 years (3,708 days).
Specimen TARGET-40-NAAGKC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a392584c-928a-4b06-98a5-26c51e825ced.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGKC-10B (Blood Derived Normal), aliquot TARGET-40-NAAGKC-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0183de8-cd3e-4f77-b9cc-b2ea63230a3b

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH17 | c.8896G>A p.V2966M | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- MYO18B | c.2718C>T p.D906= | Silent (SNP) | VAF 30/208 reads (14%) | called by muse, mutect2, varscan2
- MDN1 | c.*5G>A | 3'UTR (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
